Gene-level copy-number profile of tumor specimen TCGA-HT-8563-01A from TCGA case TCGA-HT-8563, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 31.0 years (11,305 days).
Specimen TCGA-HT-8563-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.851f8c91-5a12-48d0-816f-b2ffc749666f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HT-8563-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/06658fc4-a23f-4749-8b84-bd66c4df8a2f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,180; copy number 2: 48,112; copy number 3: 3,174; copy number 4: 133; copy number 5: 220.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HT-8563-01A-11D-2391-01): tumor purity 0.46, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 220 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:39,539,581–39,619,803, 3 genes, copy number 5: AC121334.2, ABCD2, AC121334.3.
- chr12:113,583,886–118,372,907, 82 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr12:121,626,550–125,164,918, 135 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,321. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
